Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7019, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7019-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

Surgical Pathology Report

[REDACTED]

[REDACTED]

Physician(s): [REDACTED]
Phy Location: [REDACTED]

=====

CLINICAL HISTORY

[REDACTED] man has had severe headache with nausea and vomiting for about three weeks. On imaging there is a large right temporal lobe mass, with edema and transtentorial herniation, with only a linear area of enhancement.

OPERATIVE DIAGNOSES
Right temporal tumor

Operation/Specimen: A: Brain tumor, biopsy
B: Brain, excision biopsy
C: Brain, right temporal, excision biopsy

PATHOLOGICAL DIAGNOSIS:
A, B, and C. Brain, right temporal, excisional biopsies:
1. Mixed oligoastrocytoma, with atypical features.
2. MIB-1 proliferation index: 10%.
See Microscopy Description and Comment.

COMMENT

The specimens are portions of cerebral cortex and adjacent white matter. The brain is sparsely to heavily infiltrated by a glial neoplastic proliferation with a mixed oligodendroglial and astroglial phenotype. Focally, the neoplastic cells have atypical nuclei, there are mitotic figures, and the proliferation indices tend to be high (up to 10%). There is also focal subtle microvascular hyperplasia. There is no necrosis, but karyorrhexis is found without difficulty. The findings are interpreted as a mixed oligoastrocytoma that is undergoing

[page 2 of 5]
anaplastic transformation. The tumor does not have enough features to be upgraded.

The morphological features may be correlated with clinical, imaging, and operative findings for their final interpretation and patient's follow up.

Electronically Signed Out

=====

PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay (LOH)

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S1612, D1S496, D19S1182, PLA2G4C

Results-Comments

Testing performed on DNA extracted from paraffin tissue block and a corresponding peripheral blood specimen for germline comparison.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers

on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as

backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C

(with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the

first line markers at that chromosome arm are uninformative or otherwise

ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a

stand-alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] as required by [REDACTED] regulations. It has not been cleared or approved for

[page 3 of 5]
specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the AP Molecular Pathology laboratory as required by regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

=====

INTRA-OPERATIVE CONSULTATION

A.

[page 4 of 5]
Brain tumor, biopsy: Glioma with oligodendroglial and astrocytic features.

Moderately pleomorphic, but no definite other high-grade features.

Frozen

section and smears performed at [REDACTED] and results reported to

the Physician of Record. [REDACTED]

[REDACTED]
[REDACTED] Senior Staff Pathologist

GROSS DESCRIPTION

A. Brain tumor, biopsy:

Received labeled with the patient's name and MRN are 2 fragments of homogeneous appearing tan tissue, approximately 1.2 x 0.8 x 0.4 cm in aggregate. Portions are used for frozen sections and smears. The frozen

residual is submitted in A1 and the unfrozen tissue is submitted in A2.

B. Brain, excision biopsy:

FIXATIVE: None. NO. PIECES: 1 fragment of tan-pink, glistening, hemorrhagic

soft tissue. SIZE/VOL: 3.3 x 1.5 x 0.5 cm. CASSETTES: 2, [REDACTED]

C. Brain, right temporal, excision biopsy:

FIXATIVE: None. NO. PIECES: 3 fragments of tan-pink, glistening, hemorrhagic

soft tissue. SIZE/VOL: 1.2 up to 1.3 cm. CASSETTES: 1, [REDACTED]
[REDACTED]
[REDACTED]

MICROSCOPIC DESCRIPTION

H and IMMUNOHISTOCHEMISTRY: The cerebrum is diffusely and focally heavily

infiltrated by a glial neoplastic proliferation. The GFAP demonstrates

frequent reactive-type astrocytes. A majority of neoplastic cells strongly

over express the p53 protein. With the MIB-1 the proliferation index may go

up to about 10% (assuming that 50% of cells are neoplastic). Focally the

mitotic rate may be three mitoses / ten high power fields. The CD31 and CD34

demonstrate focal subtle microvascular hyperplasia.

ICD-9(s):

191.9 191.9

Billing Fee Code(s):
[REDACTED]

[page 5 of 5]
Histo Data

Part A: Brain tumor, biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	
CD31-DA x 1	2	[REDACTED]	
CD34-DA x 1	2	[REDACTED]	
mGFAP-DA x 1	2	[REDACTED]	
H/E x 1	2	[REDACTED]	
MGMT-curls x 1	2	[REDACTED]	Do LOH also.
Thanks.			
MIB1-DA x 1	2	[REDACTED]	
P53DO7 x 1	2	[REDACTED]	

Part B: Brain, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
CD31-DA x 1	2	[REDACTED]	
H/E x 1	2	[REDACTED]	
MIB1-DA x 1	2	[REDACTED]	

Part C: Brain, right temporal, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
CD31-DA x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
MIB1-DA x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file ffa14a7d-218a-4ddc-91f1-1a14023f01af (TCGA-DU-7019.A389C9C9-E639-49C6-A8D8-56F79834E6A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).